TCGA case TCGA-32-1973 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital (AZ). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6d64459-e639-4557-bf10-a9148263ee26

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 21 years; Vital status: Dead; Days to death: 641 days (1.8 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 21.2 years (7,756 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 22 days; Days to treatment end: 64 days; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Motexafin Gadolinium; Treatment intent type: Adjuvant; Days to treatment start: 23 days; Days to treatment end: 32 days; Number of cycles: 2; Prescribed dose: 5; Prescribed dose units: mg/kg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 23 days; Days to treatment end: 64 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 417 days (1.1 years); Number of cycles: 12; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Afatinib Dimaleate; Initial disease status: Progressive Disease; Days to treatment start: 521 days (1.4 years); Days to treatment end: 542 days (1.5 years); Number of cycles: 1; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 521 days (1.4 years); Days to treatment end: 542 days (1.5 years); Number of cycles: 1; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab + Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 549 days (1.5 years); Days to treatment end: 631 days (1.7 years); Number of cycles: 6; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 22.6 years (8,263 days); Days to diagnosis: 507 days (1.4 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (2 entries)
- Day 507 (post initial treatment): Progression or recurrence: Yes; Days to progression: 507 days (1.4 years).
- Days to follow up: 641 days (1.8 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-32-1973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-32-1973-01A-01-TS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 85; Percent normal cells: 50; Percent necrosis: 20; Percent stromal cells: 0.
  Slide TCGA-32-1973-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 95; Percent normal cells: 20; Percent necrosis: 40; Percent stromal cells: 0.
- Sample TCGA-32-1973-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 6: Pharmaceutical therapy drug name: BIBW2992.
- Drug treatment 7: Pharmaceutical therapy drug name: Metexafin Gadolinium.
- Drug treatment 7, Route of administrations: Route of administration: IP; Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 641 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 641 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 507 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-32-1973-01): tumor purity 0.88, ploidy 1.86, whole-genome doublings 0 (call status: legacy_call).
